Surgical pathology report (de-identified scan), TCGA case TCGA-06-5859, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5859-01A (Primary Tumor).

[page 1 of 6]
=====

CLINICAL HISTORY

developed and on imaging has a 3.1 cm right heterogeneous mass involving basal ganglia, and frontal and temporal lobes, with central enhancement.

OPERATIVE DIAGNOSES

TOC: 11 am Right temporal mass

Operation/Specimen: A: Right temporal tumor, resection
B: Right temporal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right frontal, biopsy and excision:

1. Glioblastoma, with leptomeningeal invasion.
2. MIB-1 proliferation index: 50%.

See Microscopy Description and Comment.

COMMENT

The specimen is portions of cerebrum that are slightly to heavily infiltrated by a glial neoplastic proliferation. The neoplastic nuclei tend to be round, are distributed within a dense gliofibrillary background in the solid areas, and have proclivity for the white matter. Focally, there is brisk mitotic activity (up to 20 mitoses / ten high power fields), and the MIB-1 proliferation index is high at about 50% in the more active areas. On one slide from the there is glial neoplasm with tumor necrosis, microvascular cellular proliferation, and necrotizing vasculopathy with thrombosis.

The neoplasm is a glioblastoma multiforme (WHO grade IV).

[page 2 of 6]
In part A the tumor is very cellular. In part B the cerebrum is sparsely to moderately infiltrated by the neoplasm and the glioma is present within the leptomeninges.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

A slide was examined and no microdissection was needed. A very low level amplification was detected in the first run (1 of 2 PCRs), but we were unable to reproduce this result in repeat PCR reaction. The amplicon level appears to be below our assay detection level. The housekeeping control gene COL2A1 showed adequate amplification. Therefore, we favor the low level positivity as background.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

[page 3 of 6]
stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out
[REDACTED]

Interpretation

There is deletion at telomeric locus (D1S1612) on chromosome 1p and telomeric loci on chromosome 19q (two loci- D19S606, PLA2G4C) suggestive of partial deletion of chromosome arms of 1p and 19q.

Informative loci: D1S496, D1S1612, D19S219, D19S606, PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block. DNA extracted from a corresponding blood specimen was used as normal reference control.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance

[page 4 of 6]
characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out
[REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

H slide was reviewed and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target

in glioblastoma because it is amplified, overexpressed, and/or mutated in up

to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

[page 5 of 6]
FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Right temporal tumor, resection:
1. Glioma, consistent with high histologic grade. Touch and crush cytology preps.
2. Glioma. 1 frozen block.

[REDACTED]
Telepathology consultation with [REDACTED]
Frozen section performed at [REDACTED]

[REDACTED] and called to the Physician of record.

GROSS DESCRIPTION

A.
Right temporal tumor, resection:
SITE: Right temporal tumor. FIXATIVE: Formalin. TYPE: biopsies. NO. PIECES:
4. SIZE/VOL: 14 x 10 x 3 mm. in aggregate. CASSETTES: A1 frozen section remnant, A2 all remaining tissue. [REDACTED]

B.
Right temporal tumor, excision biopsy:
CONTAINER LABEL: right temporal tumor
FIXATIVE: formalin
GENERAL: received is a 4.0 x 4.0 x 1.9 cm ragged tan soft portion of brain.

Sectioning reveals multiple minute pink dots. The remaining cut surfaces are tan and soft.

SECTIONS: 3, [REDACTED]
[REDACTED]
[REDACTED]

[page 6 of 6]
[REDACTED]

IMMUNOHISTOCHEMISTRY: There is dense gliofibrillogenesis by the neoplastic cells. A majority of cells over expresses the p53 protein. The CD34 depicts focal microvascular proliferation. With the MIB-1 there is a proliferation index of about 50% in the more active areas.

SPECIAL STAIN: The Masson's trichrome demonstrates growth of the neoplasm within the leptomeningeal space.

ICD-9(s):
405.01 405.01

[REDACTED]

Histo Data

Part A: Right temporal tumor, resection

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
CD34-DA x 1	2	[REDACTED]	
EGFR-curles x 1	2	[REDACTED]	
mGFAP-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
LOH-curles x 1	2	[REDACTED]	1p, 19q, please.
MGMT-curles x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	
P53DO7 x 1	2	[REDACTED]	

Part B: Right temporal tumor, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
mGFAP-DA x 1	3	[REDACTED]	
H/E x 1	3	[REDACTED]	
M Trich x 1	3	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 89b7e501-5be2-4836-9a08-723ef8449fb3 (TCGA-06-5859.9BAEB8A0-E852-4729-BFC6-E4666A1F0A37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).